Gene-level copy-number profile of tumor specimen TCGA-52-7810-01A from TCGA case TCGA-52-7810, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.9 years (22,241 days).
Specimen TCGA-52-7810-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.62354375-28c5-414a-a5f9-663c8417d94e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-52-7810-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/61f0ae9d-3935-444a-8e9a-fc668c73d650

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,162; copy number 2: 18,283; copy number 3: 11,657; copy number 4: 19,077; copy number 5: 2,175; copy number 6: 3,574; copy number 7: 391; copy number 8: 598; copy number 9: 1,330; copy number 10: 163; copy number 11: 1,155; copy number 12: 16; copy number 13: 103; copy number 14: 61; copy number 20: 38; copy number 21: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-52-7810-01A-11D-2121-01): tumor purity 0.51, ploidy 3.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:133,117,004–133,119,052, 1 gene: AC011755.1.
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr5:60,304,047–60,304,151, 1 gene: RNU6-806P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,666 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–12,769,457, 184 genes, copy number 9–12 (broad region; genes not listed).
- chr3:88,948,142–90,184,733, 8 genes, copy number 11: ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P.
- chr3:129,440,036–136,205,915, 118 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr3:141,051,347–190,167,651, 794 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr5:58,198–29,396,095, 444 genes, copy number 9–14 (broad region; genes not listed).
- chr5:34,651,457–45,895,970, 185 genes, copy number 9–14 (broad region; genes not listed).
- chr8:100,957,883–145,066,685, 679 genes, copy number 11 (broad region; genes not listed).
- chr11:87,037,844–87,328,824, 1 gene, copy number 9 (within-gene range 7–9): TMEM135.
- chr11:87,258,851–92,161,889, 108 genes, copy number 9 (broad region; genes not listed).
- chr12:45,444,766–48,191,207, 76 genes, copy number 11–20 (broad region; genes not listed).
- chr12:48,202,083–48,203,387, 1 gene, copy number 20: OR10AD1.
- chr22:47,115,838–50,270,767, 68 genes, copy number 11–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
